Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2P0, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2P0-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: M

HCN:

Ordering

MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Nck: left lower
2. Nck: left neck level 6
3. Thyroid: Total thyroid, stitch-left superior pole
4. Lymph node: Left tracheal esophageal gutter node

ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

lw
8/24/11

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph nodes, 5 of 30
- (Left lower neck) dissection specimen
2. No pathological diagnosis: Soft tissue (left neck level VI) excisional biopsy
3. Widely invasive classical variant papillary carcinoma with hobnail cell change and psammomatous dissemination, 2.1 cm, left; mild follicular nodular disease and mild reactive C-cell hyperplasia: Thyroid
No pathological diagnosis: Parathyroid, left perithyroidal
-Total thyroidectomy specimen
4. Metastatic papillary thyroid carcinoma: Lymph nodes, 4 of 4
No pathological diagnosis: Thyroid
- (Site listed as "left tracheoesophageal node") dissection specimen

Comment

The dominant tumor is a 2.0 cm widely invasive classical variant which shows psammomatous dissemination throughout the left lobe, including involvement of lymphatic channels. However, there is no unequivocal evidence of vascular invasion.

Synoptic Data

Procedure:

Total thyroidectomy with left neck dissection

Received:

Fresh

Specimen Integrity:

Intact

[page 2 of 3]
Specimen Size:	Right lobe: 7.0 cm 2.5 cm 2.0 cm Left lobe: 5.9 cm 3.0 cm 2.4 cm Isthmus +/- pyramidal lobe: 4.0 cm 1.2 cm 1.2 cm Left neck dissection: 6.0 cm 4.2 cm 2.0 cm
Specimen Weight:	40.8 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 2.1 cm Additional dimension: 1.8 cm Additional dimension: 1.3 cm
Histologic Type:	Papillary carcinoma, classical (usual) Papillary carcinoma, other variant: with hobnail cell change Classical (papillary) architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Indeterminate
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes Number of regional lymph nodes examined: 34 Number of regional lymph nodes involved: 9 Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease Parathyroid gland(s), within normal limits Other: intrathyroidal psammomatous dissemination throughout the left lobe, mild reactive C-cell hyperplasia

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

verified by:

Electronically

[page 3 of 3]
Clinical History

Thyroid cancer

Gross Description

1 The specimen labeled with the patient's name and as "left lower neck", consists of multiple pieces of unoriented fibrofatty tissue with the largest measuring 6.0 x 4.2 x 2.0 cm. There is a tumor measuring 2.5 x 1.5 x 1.2 cm located at the closest soft tissue margin. The tumor is cystic and filled with hemorrhagic fluid. Within the remainder of the fibrofatty tissue multiple lymph nodes ranging from 0.3 to 1.8 in greatest dimension are identified. The outside of the specimen is painted with silver nitrate. One piece of tumor is stored frozen.

Representative sections submitted as follows:

1A-1C tumor

1D-1F multiple nodes per block

1G two nodes

2. The specimen labeled with the patient's name and as "left neck level 6", consists of a portion of fibroadipose tissue that measures 4.5 x 2.5 x 1.4 cm. No lymph nodes are identified grossly within the fibrofatty tissue. Representative sections are submitted.

2A-B fibrofatty and soft tissue

3. The specimen labeled with the patient's name and as "total thyroid stitch-left superior pole" consists of a thyroid gland that is oriented with a suture marking the left superior pole and weighs 40.8 g (fresh). The right lobe measures 7.0 cm SI x 2.5 cm ML x 2.0 cm AP, the left lobe measures 5.9 cm SI x 3.0 cm ML x 2.4 cm AP and the isthmus measures 4.0 cm SI x 1.2 cm ML x 1.2 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The left lobe contains a well delineated nodule that measures 2.1 cm SI x 1.8 cm ML x 1.3 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Two sections from of left lobe nodule and two pieces of normal tissue from the right lobe are stored frozen. The remainder of the specimen is submitted as follows:

3A-N right lobe, superior to inferior

3C, D, E, F, H, K, L: one piece bisected per block

3I-J: one piece bisected

3A, 3N: two pieces in block

3O-Q isthmus

3P-Q: One piece bisected

3R-AE left lobe, superior to inferior

3S-two pieces in block

3W, 3X: one piece bisected per block

3Y-Z: one piece bisected

4. The specimen labeled with the patient's name and as "left tracheoesophageal node" consists of a piece of fibrofatty tissue that measures 2.1 x 2.0 x 0.8 cm. Within the fibrofatty tissue multiple lymph nodes measuring from 0.3 to 0.7 cm in greatest dimension are identified.

Representative sections submitted as follows:

4A 3 nodes

4B two nodes

Source: NCI Genomic Data Commons file e08e0a7a-93e2-45f6-a89d-3db6f28c316f (TCGA-EM-A2P0.EA891EB1-8E94-4D95-88CD-65E5B2B6F43D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).